Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A22Q, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A22Q-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3

Carcinoma, papillary, follicular variant

8340/3

Site: thyroid, NOS CT3.9

for 4/26/11

Surgical Pathology Consultation Report

Patient

Name:

MRN:

DOB:

Gender: M

HCN:

Ordering MD:

Copy To:

Service:

Visit #:

Location:

Facility:

Accession #:

Collected:

Received:

Reported:

Specimen(s) Received

1. Lymph-Node: right paratracheal node dissection
2. Lymph node: Left paratracheal node dissection
3. Thyroid: Total thyroidectomy stitch Rt. superior pole

Diagnosis

1. No pathological diagnosis: Lymph nodes, 3 (right paratracheal) dissection specimen
2. No pathological diagnosis: Lymph nodes, 3 (left paratracheal) dissection specimen
3. Papillary carcinoma, follicular variant, 5.4 cm, right; focal thyroiditis: Thyroid
No pathological diagnosis: Lymph nodes, 2, left perithyroidal
No pathological diagnosis: Lymph node, isthmus
No pathological diagnosis: Parathyroid, left perithyroidal
- Total thyroidectomy specimen

Synoptic Data

Procedure:	Other: Total thyroidectomy with bilateral paratracheal dissection
Received:	Fresh
Specimen Integrity:	Intact
Specimen Size:	Right lobe: 7.0 cm 4.1 cm 2.5 cm Left lobe: 3.9 cm 2.9 cm 0.9 cm Isthmus +/- pyramidal lobe: 4.0 cm 2.4 cm 0.3 cm
Specimen Weight:	41.0 g
Tumor Focality:	Unifocal
----- DOMINANT TUMOR -----	
Tumor Laterality:	Right lobe
Tumor Size:	Greatest dimension: 5.4cm Additional dimension: 4.0 cm

[page 2 of 2]
Histologic Type:	Additional dimension: 2.4 cm Papillary carcinoma, follicular variant Per TSS, follicular variant = 100% Follicular architecture Classical cytomorphology
Histologic Grade:	Not applicable
Margins:	Margins uninvolved by carcinoma
Tumor Capsule:	Totally encapsulated
Tumor Capsular Invasion:	Present, extent minimal
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT3: Tumor more than 4 cm, limited to thyroid or with minimal extrathyroidal extension (eg, extension to sternothyroid muscle or perithyroid soft tissues)
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis Number of regional lymph nodes examined: 9 Number of regional lymph nodes involved: 0
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	Thyroiditis, focal (nonspecific) Parathyroid gland(s), within normal limits

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically verified

by:

Gross Description

1. The specimen labeled with the patient's name and as "Lymph Node: Right paratracheal node dissection" consists of a fragment of reddish yellow tissue that measures 1.0 x 0.8 x 0.6 cm.

1A submitted in toto

2. The specimen labeled with the patient's name and as "Lymph Node: Left paratracheal node dissection" consists of 3 pieces of reddish yellow tissue that measures from 0.2 x 0.2 x 0.1 to 1.0 x 0.8 x 0.6 cm.

2A submitted in toto

3. The specimen labeled with the patient's name and as "Thyroid: Total thyroidectomy stitch right superior pole" consists of a thyroid gland that is oriented with a stitch and weighs 41.0 g. The right lobe measures 7.0 cm SI x 4.1 cm ML x 2.5 cm AP, the left lobe measures 3.9 cm SI x 2.9 cm ML x 0.9 cm AP and the isthmus measures 4.0 cm SI x 2.4 cm ML x 0.3 cm AP. The external surfaces have fibrous adhesions and are painted with silver nitrate. No parathyroid glands or lymph nodes are identified grossly. The upper mid to lower pole of the right lobe contains a well delineated nodule that measures 5.4 cm SI x 4.0 cm ML x 2.4 cm AP. The remainder of the thyroid tissue is unremarkable. Sections of right lobe nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

3A-S right lobe, superior to inferior

3T-U isthmus

3V-AA left lobe, superior to inferior

Source: NCI Genomic Data Commons file cfcbfa47-5c8b-4968-9085-82d8e88756bd (TCGA-EM-A22Q.0BD8BD3E-681E-4604-8385-B3829BFD83CD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).